Somatic mutation profile of tumor specimen TCGA-BF-A5ER-01A (aliquot TCGA-BF-A5ER-01A-12D-A27K-08) from TCGA case TCGA-BF-A5ER, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 63.5 years (23,199 days).
Specimen TCGA-BF-A5ER-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b2d400a-6098-4e3a-bcf5-f5b6b5c699b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BF-A5ER-10A (Blood Derived Normal), aliquot TCGA-BF-A5ER-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f01c2ab4-75c7-4024-b864-f31410cdbe1d

The open-access MAF lists 238 somatic variants for this specimen: 151 protein-altering or splice-affecting, 81 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 135, Silent 81, Nonsense Mutation 5, Splice Site 4, Frame Shift Del 4, 3'UTR 2, Frame Shift Ins 1, RNA 1, Intron 1, In Frame Del 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASS1 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs765338121, CM031628, COSV100752790; ClinVar: likely pathogenic; called by muse, mutect2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/106 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/105 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 23/72 reads (32%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.4802C>T p.S1601L (on ENST00000272895 / NM_173076.3; = p.S1283L on NM_015657.3) | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1215880603, COSV99791541; called by muse, mutect2, varscan2
- ABCA13 | c.2897C>T p.S966F | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.05); catalogued as COSV101330154; called by muse, mutect2, varscan2
- ABCC3 | c.487G>A p.G163S | Missense Mutation (SNP) | VAF 65/165 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.041); catalogued as COSV53319042; called by muse, mutect2, varscan2
- ADAMTSL3 | c.154G>A p.G52R | Missense Mutation (SNP) | VAF 78/168 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99720656; called by muse, mutect2, varscan2
- ADGRD1 | c.1441C>T p.P481S | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.791); catalogued as rs865931428, COSV99896659; called by muse, mutect2, varscan2
- ADGRV1 | c.12161C>T p.S4054L | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as COSV101316244; called by muse, mutect2, varscan2
- ADGRV1 | c.14758G>A p.V4920I | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as rs1219145301, COSV101316351; called by muse, mutect2, varscan2
- ADHFE1 | c.1398_1399del p.Y467Lfs*21 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs748013496; called by mutect2, pindel
- ALPK2 | c.4055C>T p.S1352F | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0.015); catalogued as COSV100864732; called by muse, mutect2, varscan2
- ANKZF1 | c.261+2T>C p.X87_splice | Splice Site (SNP) | VAF 27/73 reads (37%) | catalogued as COSV99850815; called by muse, mutect2, varscan2
- AOC1 | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 50/65 reads (77%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs200778786; called by muse, mutect2, varscan2
- ARHGAP11A | c.1417C>T p.R473* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as rs776172390, COSV64380835; called by muse, mutect2
- B3GAT1 | c.343C>T p.L115F | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.632); catalogued as COSV100438139, COSV57000915; called by muse, mutect2, varscan2
- BRD7 | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 27/41 reads (66%) | catalogued as COSV67158826; called by muse, mutect2, varscan2
- C10orf53 | c.218G>A p.G73E | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65107823; called by muse, mutect2, varscan2
- C2CD2L | c.1906C>T p.H636Y | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100371456; called by muse, mutect2, varscan2
- CADPS2 | c.1951C>T p.Q651* | Nonsense Mutation (SNP) | VAF 25/105 reads (24%) | catalogued as rs768699477, COSV100460877; called by muse, mutect2, varscan2
- CCDC88B | c.3551G>A p.G1184D | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs752706848, COSV57266429, COSV57267073; called by muse, mutect2, varscan2
- CD38 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.129); catalogued as COSV99882974; called by muse, mutect2, varscan2
- CDC14B | c.1019C>T p.T340I | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.052); catalogued as COSV99686149; called by muse, mutect2, varscan2
- CDC20B | c.1232C>T p.P411L | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99697284; called by muse, mutect2, varscan2
- CHD5 | c.2279C>T p.T760I | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs747682429, COSV99314689; called by muse, mutect2, varscan2
- COL7A1 | c.4996C>T p.R1666W | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs764442838, COSV60401472; called by muse, mutect2, varscan2
- CRYZL1 | c.67-1G>A p.X23_splice | Splice Site (SNP) | VAF 19/60 reads (32%) | catalogued as rs1327830698, COSV99281131; called by muse, mutect2, varscan2
- CSMD3 | c.5717C>T p.P1906L (on ENST00000297405 / NM_001363185.1; = p.P1802L on NM_052900.3) | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV52194075, COSV99844446; called by muse, mutect2, varscan2
- CYP4F11 | c.1395C>T p.P465= | Splice Region (SNP) | VAF 117/302 reads (39%) | catalogued as COSV99931060; called by muse, mutect2, varscan2
- CYRIB | c.725G>A p.S242N | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.826); catalogued as COSV101310292; called by muse, mutect2, varscan2
- DCST1 | c.287C>T p.T96I | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV55059147; called by muse, mutect2, varscan2
- DDHD1 | c.896C>T p.P299L (on ENST00000323669; = p.P496L on NM_030637.3) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100079917; called by muse, mutect2, varscan2
- DENND4C | c.1348C>T p.P450S | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100991533; called by muse, mutect2, varscan2
- DHX30 | c.263C>G p.T88R (on ENST00000445061 / NM_138615.3; = p.T49R on NM_014966.3) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100820099; called by muse, mutect2, varscan2
- DMXL2 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 69/182 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99198338; called by muse, mutect2, varscan2
- DNAH10 | c.6955C>T p.R2319* (on ENST00000409039; = p.R2258* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 20/40 reads (50%) | catalogued as rs370961430; called by muse, mutect2, varscan2
- DSCAM | c.2311G>A p.D771N | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.12); catalogued as rs267606128, COSV68029375; called by muse, mutect2, varscan2
- DTNA | c.16G>T p.G6W | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99314613; called by muse, mutect2, varscan2
- DTNBP1 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV59037464, COSV59043932; called by muse, mutect2, varscan2
- EFHB | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV55549103, COSV99860116; called by muse, mutect2
- ENAM | c.2338C>T p.P780S | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.359); catalogued as COSV101253294; called by muse, mutect2, varscan2
- EPHA4 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs765633667, COSV99917303; called by muse, mutect2, varscan2
- EPHA6 | c.2974C>T p.P992S | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67600205; called by muse, mutect2, varscan2
- EVI5L | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99563469; called by muse, mutect2, varscan2
- EXD1 | c.466-1G>A p.X156_splice | Splice Site (SNP) | VAF 11/44 reads (25%) | catalogued as rs746622334, COSV100153797; called by muse, mutect2, varscan2
- FAM83B | c.2992G>A p.G998R | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0.197); catalogued as rs1214784542, COSV100174887; called by muse, mutect2, varscan2
- FCRL1 | c.362G>A p.G121E | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.538); catalogued as rs1214381684, COSV100839875; called by muse, mutect2, varscan2
- FCRL5 | c.2362C>T p.H788Y | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV62512252; called by muse, mutect2, varscan2
- FIZ1 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.054); catalogued as COSV99684705; called by muse, mutect2, varscan2
- GAD1 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.96); catalogued as COSV100713911; called by muse, mutect2, varscan2
- GLG1 | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.301); catalogued as COSV99216189; called by muse, mutect2, varscan2
- GPM6A | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.968); catalogued as rs1400985112, COSV99705144; called by muse, mutect2, varscan2
- HAX1 | c.722C>T p.T241I | Missense Mutation (SNP) | VAF 64/189 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs775332917, COSV99672085; called by muse, mutect2
- HDC | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 91/230 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as rs769839707, COSV51068917; called by muse, mutect2, varscan2
- HOXA2 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99761322; called by muse, mutect2, varscan2
- HTR3A | c.1225C>T p.R409W | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs746743815, COSV55470741, COSV55471627; called by muse, mutect2, varscan2
- IFIH1 | c.1205A>C p.E402A | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.501); catalogued as COSV99718819; called by muse, mutect2, varscan2
- IGSF21 | c.1027G>A p.G343R | Missense Mutation (SNP) | VAF 64/186 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52127135; called by muse, mutect2, varscan2
- IL36G | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); catalogued as rs771089638, COSV99381255; called by muse, mutect2, varscan2
- INTU | c.1097C>T p.S366F | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99611945; called by muse, mutect2
- KCNU1 | c.659A>G p.N220S | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.023); catalogued as COSV101299404; called by muse, mutect2, varscan2
- KDM6B | c.409G>A p.G137R | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.669); catalogued as COSV99642123; called by muse, mutect2, varscan2
- KLHL2 | c.1340-1G>A p.X447_splice | Splice Site (SNP) | VAF 11/28 reads (39%) | catalogued as COSV99900227; called by muse, mutect2, varscan2
- KRT75 | c.1110G>A p.M370I | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV99359573; called by muse, mutect2, varscan2
- LGMN | c.791C>T p.T264I | Missense Mutation (SNP) | VAF 84/259 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs367813667; called by muse, mutect2, varscan2
- LIMK1 | c.593C>T p.T198I | Missense Mutation (SNP) | VAF 138/238 reads (58%) | SIFT tolerated (0.18); PolyPhen benign (0.411); catalogued as rs1479639469, COSV100283406; called by muse, mutect2, varscan2
- LRRC3B | c.598A>G p.K200E | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as COSV101185998; called by muse, mutect2, varscan2
- MAGEC3 | c.1706G>T p.W569L | Missense Mutation (SNP) | VAF 56/76 reads (74%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as COSV100025959; called by muse, mutect2, varscan2
- MAP1B | c.6661G>A p.D2221N | Missense Mutation (SNP) | VAF 60/170 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99702830; called by muse, mutect2, varscan2
- MAP3K21 | c.2279G>A p.R760Q | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs565964163, COSV64042125; called by muse, mutect2, varscan2
- MBD5 | c.1873C>T p.P625S | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as rs749574412, COSV68698339; called by muse, mutect2, varscan2
- MED1 | c.3509C>T p.T1170I | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV100328094; called by muse, mutect2, varscan2
- MMP27 | c.1364G>A p.R455Q | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs773337936, COSV99498633; called by muse, mutect2, varscan2
- MR1 | c.377G>A p.G126E | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99295020; called by muse, mutect2, varscan2
- MUC16 | c.27762G>A p.M9254I | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV67462154; called by muse, mutect2, varscan2
- MUC16 | c.14233C>T p.P4745S | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.02); catalogued as COSV67500880; called by muse, mutect2, varscan2
- MUC4 | c.1028C>T p.T343I | Missense Mutation (SNP) | VAF 66/189 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.517); catalogued as COSV100640177; called by muse, mutect2, varscan2
- MYH11 | c.2629G>A p.E877K | Missense Mutation (SNP) | VAF 172/228 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as COSV100259940; called by muse, mutect2, varscan2
- MYO7A | c.3589C>T p.L1197F | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101289246; called by muse, mutect2, varscan2
- NARF | c.1018G>T p.V340L | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100559709; called by muse, mutect2, varscan2
- NEUROD4 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54472614; called by muse, mutect2, varscan2
- NISCH | c.3746C>T p.S1249F | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.69); PolyPhen benign (0.034); catalogued as COSV100402111; called by muse, mutect2, varscan2
- NRCAM | c.632A>T p.D211V (on ENST00000379028 / NM_001371124.1; = p.D205V on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100695289; called by muse, mutect2, varscan2
- NRXN1 | c.3646C>T p.R1216C | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199888301, COSV60488178; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NUP210 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54405192; called by muse, mutect2, varscan2
- OR10G8 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as COSV70909038; called by muse, mutect2, varscan2
- OR5P2 | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as rs754458836, COSV61490124; called by muse, mutect2
- PARP6 | c.1547C>T p.S516F | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs963364934, COSV53002536; called by muse, mutect2, varscan2
- PCDHGA1 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.009); catalogued as rs898742572, COSV65294827; called by muse, mutect2, varscan2
- PCDHGB4 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV53930736; called by muse, mutect2, varscan2
- PHYH | c.899T>G p.I300S | Missense Mutation (SNP) | VAF 54/100 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV99538309; called by muse, mutect2, varscan2
- PKD2L1 | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 38/57 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100559429; called by muse, mutect2, varscan2
- PLEKHA7 | c.1757G>A p.R586Q | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs754553411, COSV100850389; called by muse, mutect2, varscan2
- POLR1A | c.1285C>T p.R429* | Nonsense Mutation (SNP) | VAF 56/144 reads (39%) | catalogued as COSV55694903; called by muse, mutect2, varscan2
- PRUNE2 | c.3104C>T p.S1035L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV100945021; called by muse, mutect2, varscan2
- PTH2R | c.898A>G p.T300A | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as rs756683987, COSV99782783; called by muse, mutect2, varscan2
- PTK2B | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100594322; called by muse, mutect2, varscan2
- RALGAPA2 | c.4645C>T p.P1549S | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV99174794; called by muse, mutect2, varscan2
- RANBP3 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99222466; called by muse, mutect2, varscan2
- RASGRP3 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 74/233 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs1360484949, COSV101274888; called by muse, mutect2, varscan2
- RPAP2 | c.1333C>T p.P445S | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as COSV101532183; called by muse, mutect2, varscan2
- RPS6KA5 | c.1798G>A p.D600N | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as COSV56219492; called by muse, mutect2, varscan2
- RYR2 | c.5291C>T p.S1764F | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV63683165; called by muse, mutect2, varscan2
- RYR2 | c.13618G>A p.E4540K | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.5); catalogued as COSV100772266; called by muse, mutect2
- RYR3 | c.7324G>A p.D2442N (on ENST00000389232; = p.D2443N on NM_001036.6) | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101213977, COSV101214019; called by muse, mutect2, varscan2
- SAMD9L | c.3460G>A p.E1154K | Missense Mutation (SNP) | VAF 56/190 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.114); catalogued as COSV100561068; called by muse, mutect2, varscan2
- SAMSN1 | c.623A>G p.N208S | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs759355843, COSV99582181; called by muse, mutect2, varscan2
- SCN11A | c.4343C>A p.T1448N | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.054); catalogued as COSV100182225; called by muse, mutect2, varscan2
- SLC25A38 | c.571T>G p.F191V | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99827920; called by muse, mutect2, varscan2
- SLC9A9 | c.315A>T p.K105N | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.29); PolyPhen benign (0.264); catalogued as COSV100342578; called by muse, mutect2, varscan2
- SLCO1B3 | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV53934611; called by mutect2, varscan2
- SLIT3 | c.2753A>G p.N918S | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV100269339; called by muse, mutect2, varscan2
- SMAD9 | c.1028G>A p.G343E (on ENST00000379826 / NM_001127217.3; = p.G306E on NM_005905.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV100614964; called by muse, mutect2, varscan2
- SORL1 | c.4495G>A p.D1499N | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1407857570, COSV99495137; called by muse, mutect2, varscan2
- SOX5 | c.2005C>T p.P669S | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.235); catalogued as COSV100507787; called by muse, mutect2, varscan2
- SOX5 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 83/320 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100507789; called by muse, mutect2, varscan2
- SOX7 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100449148; called by muse, mutect2, varscan2
- SPTB | c.4826C>T p.S1609F | Missense Mutation (SNP) | VAF 62/177 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV101072379; called by muse, mutect2, varscan2
- SYT1 | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99697022; called by muse, mutect2, varscan2
- TBC1D8B | c.3019C>T p.P1007S | Missense Mutation (SNP) | VAF 33/36 reads (92%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.822); catalogued as COSV99344434; called by muse, mutect2, varscan2
- TCEAL6 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 78/105 reads (74%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.992); catalogued as rs371834028, COSV65653824; called by muse, mutect2, varscan2
- TDRD5 | c.2329G>A p.E777K | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV54243890, COSV54252807; called by muse, mutect2, varscan2
- THBS1 | c.965G>A p.G322E | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52950878; called by muse, mutect2, varscan2
- THBS2 | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100828019; called by muse, mutect2, varscan2
- THRB | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99769712; called by muse, mutect2, varscan2
- TMEM26 | c.650G>T p.W217L | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99515684; called by muse, mutect2, varscan2
- TNFRSF9 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV101097341; called by muse, mutect2, varscan2
- TRIM40 | c.736G>A p.G246R (on ENST00000376724; = p.G217R on NM_138700.4) | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1403724963, COSV100325444; called by muse, mutect2
- TRPC7 | c.400G>A p.G134S | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as rs781686269, COSV100725912; called by muse, mutect2, varscan2
- TRPM7 | c.4069C>T p.P1357S | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs1325804887, COSV100540232; called by muse, mutect2, varscan2
- TSPAN2 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs753573127, COSV65690375; called by muse, mutect2, varscan2
- TTLL11 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV100389184; called by muse, mutect2
- TTN | c.82286G>A p.G27429E (on ENST00000591111; = p.G20005E on NM_003319.4) | Missense Mutation (SNP) | VAF 25/59 reads (42%) | PolyPhen probably damaging (1); catalogued as COSV100625979; called by muse, mutect2, varscan2
- TTN | c.77603G>A p.R25868Q (on ENST00000591111; = p.R18444Q on NM_003319.4) | Missense Mutation (SNP) | VAF 53/134 reads (40%) | PolyPhen probably damaging (0.996); catalogued as rs1246168127, COSV59940895; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.35177C>T p.P11726L (on ENST00000591111; = p.P10799L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | PolyPhen benign (0.006); catalogued as COSV100625981; called by muse, mutect2
- UBE3C | c.2027C>T p.S676F | Missense Mutation (SNP) | VAF 70/83 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV100780064; called by muse, mutect2, varscan2
- USP43 | c.2969G>A p.R990K | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as COSV99556975; called by muse, mutect2, varscan2
- XPO5 | c.2138C>T p.P713L | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs781583963, COSV99541314; called by muse, mutect2, varscan2
- ZFP57 | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 195/306 reads (64%) | SIFT tolerated (0.17); PolyPhen benign (0.057); catalogued as COSV65307213; called by muse, mutect2, varscan2
- ZMAT4 | c.262G>A p.V88M | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99910997; called by muse, mutect2, varscan2
- ZNF285 | c.1658C>T p.S553L | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as rs867815076, COSV100450102; called by muse, mutect2, varscan2
- ZNF365 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.069); catalogued as COSV101237981; called by muse, mutect2, varscan2
- ZNF442 | c.1079G>A p.C360Y | Missense Mutation (SNP) | VAF 71/208 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs1179954592, COSV99664480; called by muse, mutect2, varscan2
- ZNF710 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 84/214 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99184245; called by muse, mutect2, varscan2
- CCAR1 | c.1560_1563del p.I521Rfs*10 | Frame Shift Del (DEL) | VAF 6/55 reads (11%) | called by mutect2, pindel
- DCUN1D4 | c.90_96dup p.N33* | Frame Shift Ins (INS) | VAF 24/97 reads (25%) | called by mutect2, varscan2
- IKBKB | c.2111_2113del p.K704del | In Frame Del (DEL) | VAF 20/77 reads (26%) | called by pindel, varscan2
- KCNB2 | c.2246del p.P749Rfs*9 | Frame Shift Del (DEL) | VAF 63/343 reads (18%) | called by mutect2, pindel, varscan2
- POLR2A | c.4471C>A p.P1491T | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- SPECC1L | c.3007_3008del p.A1004Ifs*28 | Frame Shift Del (DEL) | VAF 24/82 reads (29%) | called by pindel, varscan2
- ABCC9 | c.2526G>A p.L842= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as COSV99686776; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3702C>T p.S1234= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV101002026; called by muse, mutect2, varscan2
- ALK | c.2997T>G p.P999= | Silent (SNP) | VAF 53/172 reads (31%) | catalogued as COSV101202545; called by muse, mutect2, varscan2
- ARAP3 | c.3960C>T p.I1320= | Silent (SNP) | VAF 42/137 reads (31%) | catalogued as rs267600461, COSV99499991; called by muse, mutect2, varscan2
- ARMT1 | c.24C>T p.L8= | Silent (SNP) | VAF 30/56 reads (54%) | catalogued as COSV100939844; called by muse, mutect2, varscan2
- ASPHD2 | c.255C>T p.P85= | Silent (SNP) | VAF 29/87 reads (33%) | catalogued as COSV99313550; called by muse, mutect2, varscan2
- ATG13 | c.327A>G p.K109= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as COSV100365952; called by muse, mutect2, varscan2
- ATP10B | c.966G>A p.G322= | Silent (SNP) | VAF 52/124 reads (42%) | catalogued as COSV100469667; called by muse, mutect2, varscan2
- ATP2C2 | c.2382G>A p.R794= | Silent (SNP) | VAF 56/95 reads (59%) | catalogued as rs775248461, COSV52296191; called by muse, mutect2, varscan2
- CCRL2 | c.696G>A p.Q232= | Silent (SNP) | VAF 94/214 reads (44%) | catalogued as COSV100645084; called by muse, mutect2, varscan2
- CDC14B | c.1020C>T p.T340= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as COSV99686144; called by muse, mutect2, varscan2
- CDH4 | c.411G>A p.K137= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV100849423; called by muse, mutect2, varscan2
- CENATAC | c.831C>T p.L277= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV100548887, COSV57722473; called by muse, mutect2, varscan2
- CFHR5 | c.798G>A p.V266= | Silent (SNP) | VAF 35/86 reads (41%) | catalogued as COSV99889490; called by muse, mutect2, varscan2
- CHST4 | c.600C>T p.I200= | Silent (SNP) | VAF 28/46 reads (61%) | catalogued as rs752000094, COSV58296411; called by muse, mutect2, varscan2
- CLASRP | c.252C>T p.A84= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as COSV55514601; called by muse, mutect2, varscan2
- CLECL1 | c.129G>A p.R43= | Silent (SNP) | VAF 54/97 reads (56%) | catalogued as COSV59932203; called by muse, mutect2, varscan2
- CPNE4 | c.942C>T p.F314= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as rs138712970, COSV70193647; called by muse, mutect2, varscan2
- CYP1A1 | c.672C>T p.F224= | Silent (SNP) | VAF 33/83 reads (40%) | catalogued as rs144413202; called by muse, mutect2, varscan2
- CYP1A2 | c.741C>T p.N247= | Silent (SNP) | VAF 67/146 reads (46%) | catalogued as rs542879792, COSV100673935; called by muse, mutect2, varscan2
- DNAH1 | c.7578G>A p.K2526= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV101326831; called by muse, mutect2, varscan2
- DSG4 | c.2295C>T p.T765= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as rs745428685, COSV100356314; called by muse, mutect2, varscan2
- ENPEP | c.1110G>A p.T370= | Silent (SNP) | VAF 30/79 reads (38%) | catalogued as rs780316413, COSV54456733, COSV99487550; called by muse, mutect2, varscan2
- EPHA4 | c.624C>T p.V208= | Silent (SNP) | VAF 34/96 reads (35%) | catalogued as COSV99917307; called by muse, mutect2, varscan2
- FOXD4L6 | c.657C>T p.F219= | Silent (SNP) | VAF 19/29 reads (66%) | called by mutect2, varscan2
- FRAS1 | c.1338G>A p.Q446= | Silent (SNP) | VAF 75/207 reads (36%) | catalogued as rs752641770, COSV99355108; called by muse, mutect2, varscan2
- GFM2 | c.1125C>T p.L375= | Silent (SNP) | VAF 37/84 reads (44%) | catalogued as COSV99714628; called by muse, mutect2, varscan2
- GPHB5 | c.42C>T p.L14= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as COSV100030255, COSV58485479; called by muse, mutect2, varscan2
- GPR15 | c.993G>A p.E331= | Silent (SNP) | VAF 26/80 reads (33%) | catalogued as COSV99423919; called by muse, mutect2, varscan2
- GRIN2B | c.480C>T p.I160= | Silent (SNP) | VAF 46/96 reads (48%) | catalogued as COSV74206734, COSV74207156; called by muse, mutect2, varscan2
- HAX1 | c.720A>T p.V240= | Silent (SNP) | VAF 61/190 reads (32%) | catalogued as COSV99672084; called by muse, mutect2
- HDHD5 | c.192C>T p.I64= (on ENST00000336737 / NM_033070.3; = p.I34= on NM_017829.5) | Silent (SNP) | VAF 51/141 reads (36%) | catalogued as rs777520185, COSV99324990; called by muse, mutect2, varscan2
- HEPHL1 | c.2364G>A p.R788= | Silent (SNP) | VAF 61/143 reads (43%) | catalogued as COSV100244258; called by muse, mutect2, varscan2
- HERC2 | c.9777C>T p.I3259= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as rs769159696, COSV55321972; called by muse, mutect2, varscan2
- HOXA6 | c.249G>A p.K83= | Silent (SNP) | VAF 35/80 reads (44%) | catalogued as rs144914171; called by muse, mutect2, varscan2
- IKBIP | c.24G>A p.K8= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as rs776987794, COSV100141881; called by muse, mutect2, varscan2
- INPPL1 | c.1941C>T p.F647= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV99996570; called by muse, mutect2, varscan2
- IRX1 | c.510C>T p.T170= | Silent (SNP) | VAF 53/132 reads (40%) | catalogued as rs770493837, COSV100116702; called by muse, mutect2, varscan2
- ITGB3 | c.1356C>T p.I452= | Silent (SNP) | VAF 27/57 reads (47%) | catalogued as rs868493250, COSV71383686; called by muse, mutect2, varscan2
- KCNK10 | c.717C>T p.F239= | Silent (SNP) | VAF 53/144 reads (37%) | catalogued as COSV100069102; called by muse, mutect2, varscan2
- KLHDC7A | c.1254C>T p.I418= | Silent (SNP) | VAF 28/62 reads (45%) | catalogued as COSV68769207; called by muse, mutect2
- LAMA5 | c.4929C>T p.T1643= | Silent (SNP) | VAF 51/121 reads (42%) | catalogued as COSV99441766; called by muse, mutect2, varscan2
- LARGE1 | c.1932C>T p.T644= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as rs764884886, COSV61661568; called by muse, mutect2, varscan2
- MAPK4 | c.507C>T p.F169= | Silent (SNP) | VAF 64/131 reads (49%) | catalogued as rs762000392, COSV68543795; called by muse, mutect2, varscan2
- MARCHF4 | c.747C>T p.I249= | Silent (SNP) | VAF 40/105 reads (38%) | catalogued as rs747551796, COSV56105005; called by muse, mutect2, varscan2
- MBD5 | c.3519G>A p.G1173= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as rs1014000010, COSV101290236; ClinVar: likely benign; called by muse, mutect2, varscan2
- MISP | c.357G>A p.K119= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs1406040224, COSV53119479; called by muse, mutect2, varscan2
- MS4A14 | c.1605G>A p.Q535= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as rs142235413; called by muse, mutect2, varscan2
- MTNR1B | c.186C>T p.I62= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs377160633; called by muse, mutect2, varscan2
- MUC5B | c.15963G>A p.R5321= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV101500660; called by muse, mutect2, varscan2
- MYH7B | c.1974G>A p.Q658= | Silent (SNP) | VAF 48/131 reads (37%) | catalogued as COSV53419792, COSV53420294; called by muse, mutect2, varscan2
- NFE2 | c.810C>T p.I270= | Silent (SNP) | VAF 27/57 reads (47%) | catalogued as COSV100380678, COSV100380839; called by muse, mutect2, varscan2
- NLRP12 | c.1764G>A p.K588= | Silent (SNP) | VAF 39/88 reads (44%) | catalogued as COSV100145727; called by muse, mutect2, varscan2
- OR52N1 | c.276G>A p.K92= | Silent (SNP) | VAF 35/93 reads (38%) | catalogued as COSV57693582; called by muse, mutect2, varscan2
- OR5D16 | c.213G>A p.V71= | Silent (SNP) | VAF 84/199 reads (42%) | catalogued as COSV65721999; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.798C>T p.S266= (on ENST00000374531 / NM_001037293.2; = p.S298= on NM_053016.6) | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as rs775020518, COSV57114753; called by muse, mutect2, varscan2
- PCDHB15 | c.1821C>T p.L607= | Silent (SNP) | VAF 37/115 reads (32%) | catalogued as COSV51364655, COSV99179142; called by muse, mutect2, varscan2
- PCDHB6 | c.1500C>T p.S500= | Silent (SNP) | VAF 118/316 reads (37%) | catalogued as COSV99170773; called by muse, varscan2
- PHF21B | c.687C>T p.F229= | Silent (SNP) | VAF 40/119 reads (34%) | catalogued as COSV57560758; called by muse, mutect2, varscan2
- PHLDA1 | c.507A>G p.K169= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as rs1244801360, COSV99876699; called by muse, mutect2, varscan2
- PLA2G12A | c.222C>T p.F74= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs775222025, COSV99697379; called by muse, mutect2, varscan2
- PLPPR1 | c.207C>T p.T69= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV100882915; called by muse, mutect2, varscan2
- POTED | c.474C>T p.I158= | Silent (SNP) | VAF 38/116 reads (33%) | catalogued as COSV55049254; called by muse, mutect2, varscan2
- PRSS38 | c.264C>T p.S88= | Silent (SNP) | VAF 44/144 reads (31%) | catalogued as COSV100816553; called by muse, mutect2, varscan2
- PTPRD | c.3657C>T p.L1219= | Silent (SNP) | VAF 53/116 reads (46%) | catalogued as COSV61954505; called by muse, mutect2, varscan2
- RC3H2 | c.2502C>T p.S834= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV100605958; called by muse, mutect2, varscan2
- RYR1 | c.2751G>A p.R917= | Silent (SNP) | VAF 34/94 reads (36%) | catalogued as COSV100615449; called by muse, mutect2, varscan2
- SALL3 | c.603C>T p.A201= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs769324404, COSV101610043; called by muse, mutect2, varscan2
- SALL4 | c.1230C>T p.F410= | Silent (SNP) | VAF 38/82 reads (46%) | catalogued as rs1193747049, COSV53852826; called by muse, mutect2, varscan2
- SNTN | c.39C>A p.L13= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV100662658; called by muse, mutect2, varscan2
- SRPK3 | c.174C>T p.P58= | Silent (SNP) | VAF 19/24 reads (79%) | catalogued as COSV99473372; called by muse, mutect2, varscan2
- STYK1 | c.1074C>T p.I358= | Silent (SNP) | VAF 113/204 reads (55%) | catalogued as COSV99312172; called by muse, mutect2, varscan2
- TBCD | c.2952G>T p.L984= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV100833651; called by muse, mutect2
- TIGD2 | c.502C>T p.L168= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV100392281, COSV100392446; called by muse, mutect2, varscan2
- TMEM182 | c.24C>T p.F8= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV101305409; called by muse, mutect2, varscan2
- TMX2 | c.543C>T p.S181= | Silent (SNP) | VAF 52/137 reads (38%) | catalogued as COSV99560276; called by muse, mutect2, varscan2
- TNPO2 | c.150C>T p.F50= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs201975298, COSV63509525; called by muse, mutect2, varscan2
- TRPC7 | c.885G>A p.V295= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as COSV61466352; called by muse, mutect2, varscan2
- UVSSA | c.1599C>T p.P533= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as rs779498260, COSV66230624; called by mutect2, varscan2
- ZIK1 | c.243G>A p.Q81= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV100277622; called by muse, mutect2, varscan2
- ZNF658 | c.849C>T p.T283= | Silent (SNP) | VAF 27/143 reads (19%) | catalogued as rs527598062; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851593 C>T | 3'Flank (SNP) | VAF 37/44 reads (84%) | called by muse, mutect2, varscan2
- ATP6AP1L | n.1737G>A | RNA (SNP) | VAF 21/72 reads (29%) | catalogued as COSV101205153; called by muse, mutect2, varscan2
- GPC6 | c.-2C>T | 5'UTR (SNP) | VAF 33/110 reads (30%) | catalogued as rs1278783349, COSV100989829; called by muse, mutect2, varscan2
- MEX3D | c.*190C>T | 3'UTR (SNP) | VAF 28/57 reads (49%) | catalogued as rs1196159638, COSV101183540; called by muse, mutect2, varscan2
- PPP1R9A | c.2758-2009C>T | Intron (SNP) | VAF 20/67 reads (30%) | catalogued as COSV56907480; called by muse, mutect2, varscan2
- ZNF99 | c.*605C>T | 3'UTR (SNP) | VAF 20/42 reads (48%) | catalogued as rs375203401, COSV68054645; called by muse, varscan2
